Somatic mutation profile of tumor specimen TARGET-30-PAPREJ-01A (aliquot TARGET-30-PAPREJ-01A-01D) from TARGET case TARGET-30-PAPREJ, project TARGET-NBL (Neuroblastoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 10.4 years (3,806 days).
Specimen TARGET-30-PAPREJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8966dc8a-b5c4-46b3-953a-2760ba5876e6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PAPREJ-10A (Blood Derived Normal), aliquot TARGET-30-PAPREJ-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6c25cf2f-e255-4365-ab7f-18b745935822

The open-access MAF lists 28 somatic variants for this specimen: 22 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Silent 5, Nonsense Mutation 2, Splice Site 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NF1 | c.7348C>T p.R2450* (on ENST00000358273 / NM_001042492.3; = p.R2429* on NM_000267.3) | Nonsense Mutation (SNP) | VAF 16/87 reads (18%) | hotspot (GDC flag); catalogued as rs786202457, CD000998, CM000818, COSV62193225; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ARHGEF9 | c.647G>A p.R216H | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.046); catalogued as rs1556365349, COSV53634798; called by muse, mutect2, varscan2
- C9 | c.376G>A p.G126R | Missense Mutation (SNP) | VAF 13/101 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs199939436; called by muse, mutect2, varscan2
- CASD1 | c.1634-1G>T p.X545_splice | Splice Site (SNP) | VAF 14/48 reads (29%) | catalogued as COSV51970807; called by muse, mutect2, varscan2
- COL14A1 | c.1670C>A p.P557Q | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.503); catalogued as COSV52847622; called by muse, mutect2, varscan2
- DNAH3 | c.11562C>A p.D3854E | Missense Mutation (SNP) | VAF 63/179 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.024); catalogued as COSV54504888; called by muse, mutect2, varscan2
- DRC7 | c.783G>T p.E261D | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.006); catalogued as COSV61053159; called by muse, mutect2, varscan2
- FASTKD3 | c.994G>A p.E332K | Missense Mutation (SNP) | VAF 48/123 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0.012); catalogued as rs551054714, COSV52941832; called by muse, mutect2, varscan2
- IRS4 | c.1423C>A p.Q475K | Missense Mutation (SNP) | VAF 102/184 reads (55%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.011); catalogued as COSV64532731; called by muse, mutect2, varscan2
- MKRN3 | c.1009C>A p.H337N | Missense Mutation (SNP) | VAF 43/84 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58808669; called by muse, mutect2, varscan2
- PARP10 | c.284G>C p.G95A | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.92); catalogued as COSV57296800; called by muse, mutect2, varscan2
- PIK3C2B | c.3586C>T p.R1196* | Nonsense Mutation (SNP) | VAF 8/32 reads (25%) | catalogued as COSV65809225, COSV65811863; called by muse, mutect2, varscan2
- PRMT8 | c.1180C>T p.R394C | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54211707; called by muse, mutect2, varscan2
- RAPH1 | c.1669G>A p.G557R (on ENST00000319170 / NM_213589.3; = p.G609R on NM_203365.4) | Missense Mutation (SNP) | VAF 54/150 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs945343700, COSV55581561; called by muse, mutect2, varscan2
- REV3L | c.1559C>G p.S520C | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV62615542; called by muse, mutect2, varscan2
- RORC | c.1336C>A p.L446M | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.775); catalogued as COSV59091594; called by muse, mutect2, varscan2
- S100A14 | c.245G>T p.R82M | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.053); catalogued as COSV59884381; called by muse, mutect2, varscan2
- SIGLEC7 | c.854G>A p.R285K | Missense Mutation (SNP) | VAF 60/133 reads (45%) | SIFT tolerated (0.16); PolyPhen benign (0.18); catalogued as COSV58314520; called by muse, mutect2, varscan2
- SLC35G3 | c.818C>T p.A273V | Missense Mutation (SNP) | VAF 106/219 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.011); catalogued as rs550720367, COSV52010244; called by muse, mutect2, varscan2
- SP100 | c.2086G>T p.D696Y | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV50974740; called by muse, mutect2, varscan2
- TBCD | c.3137C>T p.T1046M | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.047); catalogued as rs541191622, COSV62797876; called by muse, mutect2, varscan2
- RPS6KC1 | c.2087C>A p.P696H | Missense Mutation (SNP) | VAF 11/115 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- AASDH | c.1569A>T p.T523= | Silent (SNP) | VAF 24/59 reads (41%) | catalogued as COSV52704185; called by muse, mutect2, varscan2
- GARS1 | c.2043C>T p.P681= | Silent (SNP) | VAF 15/85 reads (18%) | catalogued as COSV66827807, COSV66828173; called by muse, mutect2, varscan2
- KL | c.2040C>T p.H680= | Silent (SNP) | VAF 35/76 reads (46%) | catalogued as rs138723796; called by muse, mutect2, varscan2
- LAMA5 | c.3912C>T p.H1304= | Silent (SNP) | VAF 7/16 reads (44%) | catalogued as rs142311649; called by muse, mutect2, varscan2
- SLC38A5 | c.1155T>C p.V385= | Silent (SNP) | VAF 26/57 reads (46%) | catalogued as COSV58333433; called by muse, mutect2, varscan2
- MAP3K3 | c.126+1950C>A | Intron (SNP) | VAF 82/295 reads (28%) | called by muse, mutect2, varscan2
